Surgical pathology report (de-identified scan), TCGA case TCGA-ND-A4WC, project TCGA-UCS (Uterine Carcinosarcoma), tissue source site Cedars Sinai, specimen TCGA-ND-A4WC-01A (Primary Tumor).

[page 1 of 5]
Patient:

Hospital No:
Date of Birth
Age/Sex: F

Pathologist:
Assistant:
Date of Procedure:
Date Received:

Accession Number:

Ordering M.D.:
Copies To:

Location:

SURGICAL PATHOLOGY REPORT

DIAGNOSIS:

A, B. UTERUS, CERVIX, BILATERAL TUBES AND OVARIES, TOTAL HYSTERECTOMY AND BILATERAL SALPINGO-OOPHORECTOMY:

- Uterine malignant mixed mullerian tumor
- Carcinomatous component is high grade with mixed endometrioid and papillary serous carcinoma
- Sarcomatoid carcinoma is also high grade, with no heterologous elements identified
- Extensive lymphovascular invasion identified
- Pathologic stage: pT1b (please see synoptic report)

C. RIGHT PELVIC LYMPH NODES, EXCISION:

- Seven lymph nodes, with no evidence of malignancy (0/7)

D. RIGHT PERIAORTIC LYMPH NODE, EXCISION:

- Three lymph nodes, with no evidence of malignancy (0/3)

E. LEFT PELVIC LYMPH NODES, EXCISION:

- Five lymph nodes, with no evidence of malignancy (0/5)

F. OMENTUM #1, RESECTION:

- Omentum with no evidence of malignancy

G. OMENTUM #2, RESECTION:

- Omentum with no evidence of malignancy

H. OMENTUM #3, RESECTION:

- Omentum with no evidence of malignancy

I. LEFT PERIAORTIC LYMPH NODES, EXCISION:

- Two lymph nodes, with no evidence of malignancy

SYNOPTIC REPORT:

Applies To:

A : UTERINE TUMOR
B : UTERUS, CERVIX, BILATERAL TUBES AND OVARIES
C : RIGHT PELVIC LYMPH NODE
D : RIGHT PERIAORTIC LYMPH NODE
E : LEFT PELVIC LYMPH NODE
F : OMENTUM #1
G : OMENTUM #2
H : OMENTUM #3

Patient Case(s):

Copy For
Page 1 of 5

PATIENT NOTIFIED OF RESULTS
DR: NURSE: DATE:

ICD-O-3
Carcinoma/mixed mullerian Tumor
Malignant 8950/3
Site: Fundus Uteri
pT1b 3/18/13
054.3

[page 2 of 5]
PATIENT:

ACCESSION #:

I : LEFT PERIAORTIC LYMPH NODE

Macroscopic

Specimen Type:	Uterus Right ovary Left ovary Right fallopian tube Left fallopian tube Parametrium Omentum
Procedure:	Total abdominal hysterectomy and bilateral salpingo-oophorectomy
Specimen Integrity:	Intact hysterectomy specimen
Lymph Node Sampling:	Pelvic lymph nodes Para-aortic lymph nodes

Microscopic

Histologic Type:	Malignant mixed mullerian tumor
Tumor Site:	Corpus Fundus Lower uterine segment
Tumor Size:	Greatest dimension: 7.1cm
Myometrial Invasion:	Invasion present Depth of invasion: 1cm Myometrial thickness: 1.6cm Greater than 50% myometrial invasion
Involvement of Cervix:	No involvement
Extent of Involvement of Other Organs:	None
Margins:	Uninvolved by invasive carcinoma
Lymphovascular Invasion:	Present Comment(s): Extensive

Pathologic Staging (pTNM) AJCC 7th Edition 2010

Primary Tumor (pT):	pT1b : Tumor invades greater than or equal to one-half of the myometrium
Regional Lymph Nodes (pN):	pN0: No regional lymph node metastasis
Number of pelvic lymph nodes examined:	12
Number of pelvic lymph nodes involved:	0
Number of para-aortic lymph nodes examined:	5
Number of para-aortic lymph nodes involved:	0
FIGO Stage:	IB

Additional Pathologic Findings

Leiomyomas
Tumor with large areas of necrosis

SURGICAL PATHOLOGY REPORT

[page 3 of 5]
PATIENT:

ACCESSION #:

HISTORY: Endometrial cancer, possible carcinosarcoma

MICROSCOPIC FINDINGS: See diagnosis.

IMMUNOHISTOCHEMISTRY:

Study / Antibody	Block	Result
Desmin	B15	Few sarcomatoid cells positive
Desmin	B8	Negative in the sarcomatoid area
S-100	B8	Negative
MyoD1	B15	Negative
Keratin (AE1/AE3)	B15	Negative in the sarcomatoid area
Keratin (AE1/AE3)	B8	Negative in the sarcomatoid area
P53 QL	B8	Positive in both carcinomatoid and sarcomatoid areas
Wilms' Tumor 1	B8	Only few carcinoma cells show focal and weak staining

*These IHC studies were interpreted in conjunction with appropriate positive and negative controls which demonstrated the expected positive and negative reactivity.

GROSS: A. UTERINE TUMOR

Labeled _____, designated "uterine tumor", and received in formalin is a 4.0 x 3.4 x 1.5 cm aggregate of multiple portions of pink-tan soft plus friable tissue ranging from 0.7 to 3.4 cm in greatest dimension.

Cut section of the tumor reveals reddish-brown hemorrhage as well as focal areas of whitish tumor ranging from 0.2 to 0.5 cm in greatest dimension.

Representative sections submitted.

A1. 3

[page 4 of 5]
PATIENT:

ACCESSION #:

B. UTERUS, CERVIX, BILATERAL TUBES AND OVARIES

Labeled _____, designated "uterus, cervix, bilateral tubes and ovaries", and received fresh in the Intraoperative Consultation Room and subsequently fixed in formalin is a 167.5 gram total hysterectomy and salpingo-oophorectomy specimen. The uterus is 11.0 x 6.1 x 5.0 cm. The left ovary is 2.0 x 1.3 x 0.5 cm. The left fallopian tube is 6.7 cm in length with a diameter up to 0.4 cm. A pinpoint lumen is identified. The right ovary is 2.2 x 0.8 x 0.7 cm. The right fallopian tube is 5.0 cm in length with a diameter up to 0.3 cm. A pinpoint lumen is identified. The endometrial cavity is 4.0 x 4.5 x 2.0 cm. The uterine wall ranges from 1.0 to 2.1 cm in thickness. The endocervical canal is 3.0 cm in length with a circumference of 2.5 cm. The external cervical os is 1.5 cm in diameter. The endometrial lining is up to 0.1 cm in thickness. Also received separately in the container is a 6.0 x 4.8 x 3.8 cm reddish-brown blood clot.

There is a 7.1 x 7.7 x 3.0 cm polypoid mass in the posterior and anterior uterine corpus. The mass is whitish tan and friable. The tumor extends from the uterine fundus and down to the lower uterine segment. The cervix appears free of tumor. The tumor appears to invade into the myometrium at its deepest point in the posterior uterine corpus approximately 0.5 cm.

Approximately two fibroids are identified in the posterior wall measuring 1.0 and 2.0 cm in greatest dimension. No necrosis hemorrhage or calcifications are identified within the fibroids. The ovaries and fallopian tubes are grossly unremarkable. Gross photographs obtained.

Slide key:

- B1. Frozen section remnant #1 – 1
- B2. Frozen section #2 – 1
- B3. Left parametrium shaved – 1
- B4. Right parametrium shaved – 1
- B5. Anterior cervix – 1
- B6. Posterior cervix – 1
- B7. Inferior most portion of tumor in anterior wall – 1
- B8, B9. Superior portion of tumor anterior wall bisected – 1 each
- B10. Inferior portion of tumor posterior wall – 1
- B11. Posterior uterine wall – 1
- B12. Uterine fundus with tumor – 1
- B13. Additional posterior wall – 1
- B14. Additional posterior wall – 1
- B15. Uninvolved anterior endometrium – 1
- B16. Leiomyomas - 2
- B17. Right ovary - 1
- B18. Right fallopian tube - 3
- B19. Left ovary - 1
- B20. Left fallopian tube - 3

C. RIGHT PELVIC LYMPH NODE

Labeled _____, designated "right pelvic lymph node", and received in formalin is a 7.0 x 5.0 x 1.2 cm aggregate of multiple portions of fatty tissue. Approximately eight lymph nodes are identified ranging from 0.4 to 3.0 cm in greatest dimension. Lymph nodes entirely submitted.

- C1. Two possible lymph nodes – 2
- C2. Lymph nodes – multiple
- C3. One lymph node – 2
- C4. Three possible lymph nodes – 3

D. RIGHT PERIAORTIC LYMPH NODE

Labeled _____, designated "right periaortic lymph node", and received in formalin is a 5.0 x 1.5 x 0.4 cm portion of fibroadipose tissue. Approximately three lymph nodes are identified within the specimen ranging from 0.3 to 0.5 cm in greatest dimension. Entirely submitted.

[page 5 of 5]
PATIENT:

ACCESSION #:

D1. Multiple

E. LEFT PELVIC LYMPH NODE

Labeled _____, designated "left pelvic lymph node", and received in formalin is a 4.5 x 3.5 x 1.2 cm aggregate of multiple portions of fibroadipose tissue ranging from 0.4 to 2.0 cm in greatest dimension. Approximately six possible lymph nodes are identified ranging from 0.4 to 2.1 cm in greatest dimension. Lymph nodes entirely submitted.

E1, E2. Multiple each

F. OMENTUM #1

Labeled _____, designated "omentum #1", and received in formalin is a 14.0 x 13.5 x 0.6 cm portion of yellow omental fat. No discrete nodules or lesions are identified. Representative sections submitted.

F1-F3. Multiple each

G. OMENTUM #2

Labeled _____, designated "omentum #2", and received in formalin is a 20.0 x 9.5 x 1.3 cm portion of yellow omental fat. No nodules or any other lesions are identified. Representative sections submitted.

G1-G3. Multiple each

H. OMENTUM #3

Labeled _____, designated "omentum #3", and received in formalin is a 12.4 x 13.0 x 1.2 cm portion of yellow omental fat. No nodules or lesions are identified. Representative sections submitted.

H1-H3. Multiple each

I. LEFT PERIAORTIC LYMPH NODE

Labeled _____, designated "left periaortic lymph node", and received in formalin is a 2.5 x 2.4 x 0.4 cm aggregate of multiple portions of fatty tissue. Approximately two lymph nodes are identified ranging from 0.2 to 0.3 cm in greatest dimension. Entirely submitted.

I1. Multiple

Gross dictated by _____

INTRAOPERATIVE CONSULTATION: _____
OPERATIVE CALL _____
OPERATIVE CONSULT (FROZEN): _____

FSB. UTERUS, CERVIX, BILATERAL TUBES AND OVARIES:

- Poorly differentiated adenocarcinoma; involving more than 60% depth of the uterine wall

I have personally examined the specimen, interpreted the results, reviewed the report and signed it electronically.
Electronically signed _____

Site	10/26/13	Yes	No
IPAC Discrepancy			✓
Second Malignancy History			✓

SURGICAL PATHOLOGY REPORT

Source: NCI Genomic Data Commons file c131460b-1efe-4bcb-bccd-cc0da418076b (TCGA-ND-A4WC.9B899153-4DC8-445B-85B7-9DCBFB1E34A3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).